Somatic mutation profile of tumor specimen MP2PRT-PAUUKU-TMP1-A (aliquot MP2PRT-PAUUKU-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAUUKU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,858 days).
Specimen MP2PRT-PAUUKU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60779168-e9dc-4f30-b237-3977c79e097d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUKU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUKU-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5870c3f2-590c-4e4a-bd93-95d26b3b0737

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Nonsense Mutation 3, Silent 3, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4774C>T p.R1592* | Nonsense Mutation (SNP) | VAF 32/154 reads (21%) | catalogued as rs1057518410, COSV57432438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC57 | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 198/689 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs201954226; called by muse, mutect2, varscan2
- KRT74 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 211/509 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs569075312, COSV99977737; called by muse, mutect2, varscan2
- OXR1 | c.941C>G p.S314* (on ENST00000442977 / NM_001198532.1; = p.S313* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 98/374 reads (26%) | catalogued as COSV56323717; called by muse, mutect2, varscan2
- P2RX4 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 139/393 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs374159417; called by muse, mutect2, varscan2
- RTEL1 | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 118/342 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs200683292; called by muse, mutect2, varscan2
- SLC4A11 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 192/426 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs139524164; called by muse, mutect2, varscan2
- ZNF534 | c.1003G>T p.G335* (on ENST00000332323 / NM_001143939.3; = p.G322* on NM_001143938.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/288 reads (38%) | catalogued as COSV56522005; called by muse, mutect2, varscan2
- ABCA9 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 89/357 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPSF4 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 158/446 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH14 | c.10135C>A p.L3379I (on ENST00000445597; = p.L4387I on NM_001367479.1) | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DUSP6 | c.962_999delinsGG p.D321_N333delinsG | In Frame Del (DEL) | VAF 131/399 reads (33%) | called by pindel, varscan2*
- E2F1 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 135/348 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD1 | c.2870C>A p.T957N | Missense Mutation (SNP) | VAF 175/658 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IRF1 | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 147/365 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT72 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 41/526 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); called by muse, mutect2
- SYCP2L | c.2415-1G>A p.X805_splice | Splice Site (SNP) | VAF 37/176 reads (21%) | called by muse, mutect2, varscan2
- TAF2 | c.1217A>T p.E406V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PROB1 | c.2217G>C p.L739= | Silent (SNP) | VAF 292/717 reads (41%) | called by muse, mutect2, varscan2
- RPTOR | c.2040C>G p.T680= | Silent (SNP) | VAF 157/498 reads (32%) | called by muse, mutect2, varscan2
- TMC1 | c.732C>T p.Y244= | Silent (SNP) | VAF 85/259 reads (33%) | catalogued as rs1406594679, COSV52773715; called by muse, mutect2, varscan2
